Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4813, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4813-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA (6.5 CM), CONVENTIONAL (CLEAR) CELL TYPE.
- B. THE CARCINOMA EXTENDS INTO RENAL VEIN FORMING AN ADDITIONAL 5.0-cm MASS.
- C. FUHRMAN GRADE: 3 OF 4.
- D. NO EXTENSION THROUGH THE RENAL CAPSULE IS NOTED.
- E. ANGIOLYMPHATIC INVASION SEEN MICROSCOPICALLY.
- F. HISTOPATHOLOGICAL STAGING: pT3b, Nx, Mx.

PART 2: VEIN, VENA CAVA, RESECTION MARGIN, EXCISION -
RENAL CELL CARCINOMA, INVOLVING THE VEIN WALL.

COMMENT:

Part 1: Additional margin from the distal ureter is submitted. Results will be issued as an addendum.

Source: NCI Genomic Data Commons file 34efc740-de9d-4813-bc48-1038067ee452 (TCGA-B0-4813.0B904450-5C80-4E14-9918-1949FA7C15FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).